Somatic mutation profile of tumor specimen 0DMRB7 from CCDI case PBCAMX, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain stem; Age at diagnosis: 10.2 years (3,735 days).
Specimen 0DMRB7: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cb9e2cec-040f-4610-a698-6825c6c199eb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DMRAP (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9ed61a7f-ec16-4687-810b-299e4d6af84a

The open-access MAF lists 34 somatic variants for this specimen: 23 protein-altering or splice-affecting, 3 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Intron 6, Silent 3, 3'UTR 2, Frame Shift Del 2, Nonsense Mutation 1, Nonstop Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H3-3A | c.83A>T p.K28M | Missense Mutation (SNP) | VAF 207/623 reads (33%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.697); catalogued as rs1057519903, COSV64731746, COSV64731769; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- MAX | c.179G>A p.R60Q | Missense Mutation (SNP) | VAF 193/1008 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52414939; called by muse, mutect2, varscan2
- PDGFRA | c.1977C>A p.N659K | Missense Mutation (SNP) | VAF 374/897 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519700, COSV57264866, COSV57265972; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACYP2 | c.295T>C p.Y99H | Missense Mutation (SNP) | VAF 201/577 reads (35%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.933); catalogued as rs1026082189; called by muse, mutect2, varscan2
- ADPRHL1 | c.3923C>T p.A1308V | Missense Mutation (SNP) | VAF 88/425 reads (21%) | SIFT tolerated, low confidence (0.16); PolyPhen possibly damaging (0.691); catalogued as rs1025308598; called by muse, mutect2, varscan2
- ETNPPL | c.1186C>T p.R396* | Nonsense Mutation (SNP) | VAF 89/582 reads (15%) | catalogued as rs146606272; called by muse, mutect2, varscan2
- PDGFRA | c.2545T>A p.Y849N | Missense Mutation (SNP) | VAF 216/1142 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57266199; called by muse, mutect2, varscan2
- PKD1 | c.7303C>T p.R2435W | Missense Mutation (SNP) | VAF 126/925 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as rs375739091; called by muse, mutect2, varscan2
- PLCE1 | c.4640C>T p.T1547M | Missense Mutation (SNP) | VAF 112/689 reads (16%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.951); catalogued as rs768854393, COSV53355318; called by muse, mutect2, varscan2
- RPL5 | c.877C>T p.R293W | Missense Mutation (SNP) | VAF 247/689 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs200315052, COSV59873342; called by muse, mutect2, varscan2
- TCEANC | c.1007G>T p.C336F (on ENST00000380600 / NM_001297563.2; = p.C366F on NM_152634.4) | Missense Mutation (SNP) | VAF 390/1066 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1284175119; called by muse, mutect2
- TTC5 | c.788G>A p.R263Q | Missense Mutation (SNP) | VAF 38/1230 reads (3%) | SIFT tolerated (0.07); PolyPhen benign (0.059); catalogued as rs1483075852; called by muse, mutect2
- ZFYVE16 | c.3205G>A p.V1069M | Missense Mutation (SNP) | VAF 134/425 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs751887083; called by muse, mutect2, varscan2
- ACBD7 | c.265T>C p.*89Qext*30 | Nonstop Mutation (SNP) | VAF 392/988 reads (40%) | called by muse, mutect2, varscan2
- ATM | c.3646del p.Y1216Ifs*7 | Frame Shift Del (DEL) | VAF 174/510 reads (34%) | called by mutect2, pindel, varscan2
- ATM | c.8759T>A p.I2920N | Missense Mutation (SNP) | VAF 265/818 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- FAM217A | c.31A>C p.S11R | Missense Mutation (SNP) | VAF 43/731 reads (6%) | SIFT tolerated (0.25); PolyPhen benign (0.005); called by muse, mutect2
- GCNA | c.2014G>C p.G672R | Missense Mutation (SNP) | VAF 373/1029 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- MBD3L3 | c.456dup p.P153Afs*56 | Frame Shift Ins (INS) | VAF 47/105 reads (45%) | called by mutect2, varscan2
- PDGFRA | c.1675T>C p.W559R | Missense Mutation (SNP) | VAF 156/948 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- POLR2A | c.3409C>T p.P1137S | Missense Mutation (SNP) | VAF 255/722 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PRKX | c.526_532del p.E176Sfs*21 | Frame Shift Del (DEL) | VAF 237/786 reads (30%) | called by mutect2, pindel, varscan2
- TNXB | c.8786C>A p.T2929N (on ENST00000647633; = p.T2682N on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 418/1178 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BIRC2 | c.1587A>G p.K529= | Silent (SNP) | VAF 153/829 reads (18%) | called by muse, mutect2, varscan2
- GPA33 | c.381C>A p.G127= | Silent (SNP) | VAF 107/969 reads (11%) | catalogued as COSV100901137; called by muse, mutect2, varscan2
- RPN1 | c.255C>T p.G85= | Silent (SNP) | VAF 271/736 reads (37%) | catalogued as rs763331685; called by muse, mutect2, varscan2
- CCDC154 | c.1179+47C>T | Intron (SNP) | VAF 191/498 reads (38%) | catalogued as rs774708319; called by muse, mutect2, varscan2
- CNTN2 | c.*21C>T | 3'UTR (SNP) | VAF 40/744 reads (5%) | catalogued as rs756380984, COSV100085168; called by muse, mutect2
- DOCK8 | c.53+348C>A | Intron (SNP) | VAF 337/926 reads (36%) | catalogued as rs778606690, COSV66688253; called by muse, mutect2, varscan2
- JMJD7-PLA2G4B | c.1184-67G>A | Intron (SNP) | VAF 185/441 reads (42%) | catalogued as rs1055788931, COSV59825930; called by muse, mutect2, varscan2
- PILRA | c.454+37G>A | Intron (SNP) | VAF 191/546 reads (35%) | catalogued as rs770085510; called by muse, mutect2, varscan2
- SNU13 | c.*19G>A | 3'UTR (SNP) | VAF 124/693 reads (18%) | catalogued as rs542239820; called by muse, mutect2, varscan2
- VIM | c.1273+31G>A | Intron (SNP) | VAF 217/483 reads (45%) | catalogued as rs770826589; called by muse, mutect2, varscan2
- WDR45 | c.973+93G>C | Intron (SNP) | VAF 65/391 reads (17%) | called by muse, mutect2, varscan2
